CCDI case PBBTSU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d8741dd8-f0a8-4fd0-bfdf-7713f07ee54b

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Craniopharyngioma, adamantinomatous: ICD-O-3 morphology code: 9351/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.2 years (4,452 days).

Biospecimens (2 samples)
- Sample 0DJGPD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DJGPE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
